HCMI case HCM-BROD-0644-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/745d26a1-1072-4ac0-b168-03f4287c32b0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Dead; Days to death: 1,130 days (3.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Small cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8041/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 68.7 years (25,096 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: yes; Prior treatment: Yes.
   Pathology details: Peripancreatic lymph nodes tested: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Treatment intent type: Neoadjuvant; Days to treatment start: 742 days (2.0 years).
   Treatment given: Treatment type: Stereotactic Radiosurgery; Treatment intent type: Neoadjuvant; Days to treatment start: 907 days (2.5 years).
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C79.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.7 years (25,809 days); Days to diagnosis: 713 days (2.0 years).
   Pathology details: Peripancreatic lymph nodes tested: 3.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Capecitabine + Gemcitabine + Nab-paclitaxel; Treatment intent type: Maintenance Therapy; Days to treatment start: 742 days (2.0 years); Days to treatment end: 944 days (2.6 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 1,130 days (3.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- CA19-9: 1439.
- CEA: 19 ng/mL; Blood test normal range upper: 3.7.
- SMAD4 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 30.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0644-C25-06B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-BROD-0644-C25-06B-01-S1-HE: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
  Slide HCM-BROD-0644-C25-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 35; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 6.
- Sample HCM-BROD-0644-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0644-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
